Surgical pathology report (de-identified scan), TCGA case TCGA-VR-AA7I, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-AA7I-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3

Carcinoma, squamous
cell NOS 8670/3

Site: Esophagus, middle
third C15.4

W 3/19/14

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Mid third)

1 - "Product of esophagectomy":

Squamous cell carcinoma of the esophagus characterized as follows:

- . Histological grade 1.
- . Measurement of neoplasia in its longest axis: 5.3 cm.
- . Measurement of neoplasia in depth: 1.3 cm
- . Ulceration present.
- . Involvement of mucosa, submucosa, muscularis propria and adventitia.
- . Spiculated pattern of infiltration.
- . Mild inflammatory infiltrate.
- . Proximal and distal surgical margins free of neoplastic involvement.
- . Radial margin is tangential.
- . Surgical margins free of neoplastic involvement.
- . Lymph nodes free of neoplastic involvement (0/15) distributed as follows:
- . . right paracardic: 0/2
- . . left paracardic: 0/2
- . . along the lesser curvature: 0/5
- . . along the left gastric artery: 0/2
- . . around the celiac trunk: 0/2

2 - "Esophageal margin":

Free of neoplastic involvement.

Diagnosis Discrepancy		W 12/20/13

Source: NCI Genomic Data Commons file a0fe74c7-50c6-4313-8f2f-4e18093fd9ba (TCGA-VR-AA7I.D93B0A27-7F42-4E00-8414-021414995552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).